Gene-level copy-number profile of tumor specimen TARGET-20-PASAFM-09A from TARGET case TARGET-20-PASAFM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,670 days).
Specimen TARGET-20-PASAFM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.72c540e8-638b-51a7-997a-fcea0b8850e7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASAFM-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/d685d50b-efe1-40cd-8f73-d487e94ec23e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2,395; copy number 2: 57,761; copy number 3: 7; copy number 4: 90.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
